Somatic mutation profile of tumor specimen TCGA-AR-A24X-01A (aliquot TCGA-AR-A24X-01A-11D-A167-09) from TCGA case TCGA-AR-A24X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.1 years (19,030 days).
Specimen TCGA-AR-A24X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28bc4621-1369-41a7-a516-967c192fa59c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A24X-10A (Blood Derived Normal), aliquot TCGA-AR-A24X-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e3b7a3b-c047-4ca7-a274-96b5356203d4

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 2, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.2165-1G>T p.X722_splice | Splice Site (SNP) | VAF 23/48 reads (48%) | hotspot (GDC flag); catalogued as rs1385720097, COSV55727626, COSV55731716; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475900, COSV60485052; called by muse, mutect2, varscan2
- ALG13 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1042682745, COSV52636394; called by muse, mutect2, varscan2
- ELF4 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.18); catalogued as COSV57451812; called by muse, mutect2, varscan2
- EP400 | c.1772A>G p.Q591R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.3); catalogued as COSV57766543; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 6/30 reads (20%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- HMGCS1 | c.930C>A p.Y310* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV57289600; called by muse, mutect2, varscan2
- HSCB | c.507T>A p.N169K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53262074; called by muse, mutect2, varscan2
- JPH3 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs755750862, COSV52465133; called by muse, mutect2
- LRRC4B | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65349484; called by muse, mutect2, varscan2
- MEGF8 | c.7249C>T p.R2417* (on ENST00000251268 / NM_001271938.2; = p.R2350* on NM_001410.3) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52078441; called by muse, mutect2, varscan2
- MIB1 | c.2903A>G p.D968G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99839156; called by muse, mutect2
- MINDY4 | c.454T>A p.F152I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV54672318; called by muse, mutect2, varscan2
- MUC5B | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs779700720, COSV71590582; called by muse, mutect2, varscan2
- PLEKHH2 | c.3545G>T p.G1182V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99174940; called by muse, mutect2, varscan2
- RBM19 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774797332, COSV55689351, COSV99926096; called by muse, mutect2, varscan2
- RPGR | c.2465G>T p.G822V (on ENST00000339363 / NM_001367249.1; = p.G617V on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV58833224; called by muse, mutect2, varscan2
- SPSB3 | c.103T>A p.W35R | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99236603; called by muse, mutect2
- TRBV5-1 | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRF5 | c.3414C>T p.C1138= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV51931106; called by muse, mutect2, varscan2
- B4GALT1 | c.549A>G p.P183= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV65707643; called by muse, mutect2, varscan2
- CARD6 | c.277A>C p.R93= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV54564871; called by muse, mutect2, varscan2
- KIAA1210 | c.2727G>T p.L909= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV68176118; called by muse, mutect2, varscan2
- PRMT7 | c.984G>T p.V328= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs768459471, COSV59832561; called by muse, mutect2, varscan2
- MACF1 | c.15832-9531A>G | Intron (SNP) | VAF 12/36 reads (33%) | catalogued as rs760649455, COSV57111602; called by muse, mutect2, varscan2
